CGCI case BLGSP-71-23-00462 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9ffe9a4d-80b7-4dfc-8913-71f353c2c029

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Age at index: 70 years; Vital status: Dead; Days to death: 28 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Classification of tumor: primary; Age at diagnosis: 70.2 years (25,640 days); Year of diagnosis: 2013; Method of diagnosis: Incisional Biopsy; Ann Arbor pathologic stage: Stage II; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 28 days; Ann Arbor extranodal involvement: Yes; Max tumor bulk site: Mandible; Sites of involvement: Mandible / Parotid gland.
   Pathology details: Lymph node involved site: Submandibular.
   Pathology details: Bone marrow malignant cells: No; Lymph node involved site: Parotid; Tumor largest dimension diameter: 10 cm.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Persistent Disease.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 0 days; ECOG performance status: 0.
- Days to follow up: 28 days; Disease response: With Tumor.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Positive.
- Lactate Dehydrogenase 495 [Blood test normal range upper: 480].

Other clinical attributes
- Day 0: Comorbidities: Hepatitis B Infection.
- Day 0: Risk factors: Hepatitis B Infection.
- Day 0: Weight: 65 kg; Height: 152 cm; BMI: 28.1.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-23-00462-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Tissue collection type: Retrospective.
  Slide BLGSP-71-23-00462-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 90; Percent normal cells: 10; Percent necrosis: 5; Percent stromal cells: 5; Percent lymphocyte infiltration: 50; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 10.
  Slide BLGSP-71-23-00462-01A-01-S1-HE: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 90; Percent normal cells: 5; Percent necrosis: 5; Percent stromal cells: 10; Percent lymphocyte infiltration: 50; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 10.
- Sample BLGSP-71-23-00462-01Z: Sample type: Tumor; Tissue type: Tumor.
  Slide BLGSP-71-23-00462-01-BCL2: Tissue microarray coordinates: B1,E2,C4.
  Slide BLGSP-71-23-00462-01-CD20: Tissue microarray coordinates: B1,E2,C4.
  Slide BLGSP-71-23-00462-01-BCL6: Tissue microarray coordinates: B1,E2,C4.
  Slide BLGSP-71-23-00462-01-CD10: Tissue microarray coordinates: B1,E2,C4.
  Slide BLGSP-71-23-00462-01-HE-1: Tissue microarray coordinates: B1,E2,C4.
  Slide BLGSP-71-23-00462-01-Ki67: Tissue microarray coordinates: B1,E2,C4.
  Slide BLGSP-71-23-00462-01-CD3: Tissue microarray coordinates: B1,E2,C4.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- History of disease, History relevant infectious diseases: History relevant infectious diagnosis: Hepatitis B Virus.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology; Extranodal site involvement: 2; Days from index date to tumor sample procurement: -23; Lymph nodes examined: No.
- Primary pathology, Extranodal involvement sites: Extranodal involvement site: Parotid Gland.
- Stage record, Ann arbor: B symptoms present indicator: No.
- Tests performed: LDH level: 495; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: BCL2.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunophenotypic analysis tested: CD20.
